Somatic mutation profile of tumor specimen TARGET-10-PARUIT-09A (aliquot TARGET-10-PARUIT-09A-01D) from TARGET case TARGET-10-PARUIT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.1 years (395 days).
Specimen TARGET-10-PARUIT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcda7176-4551-4f3f-9359-5df784b2d8fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUIT-10A (Blood Derived Normal), aliquot TARGET-10-PARUIT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f76353e8-ecba-4870-badb-7b27698912e0

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Ins 1, 3'UTR 1, Intron 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 28/83 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSMD3 | c.2065G>T p.E689* (on ENST00000297405 / NM_001363185.1; = p.E585* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as COSV52326121; called by muse, mutect2, varscan2
- PLCE1 | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776768312; called by muse, mutect2, varscan2
- SDCBP | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs372417488, COSV52705278; called by muse, varscan2
- ASCC3 | c.3060A>C p.E1020D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIGYF2 | c.2827_2828insGG p.T943Rfs*11 | Frame Shift Ins (INS) | VAF 89/187 reads (48%) | called by mutect2, pindel*, varscan2
- ITPRID1 | c.3098G>T p.C1033F | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GNAS | c.1200C>T p.A400= | Silent (SNP) | VAF 69/131 reads (53%) | catalogued as rs908810796; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 6/60 reads (10%) | catalogued as rs201441562; called by pindel, varscan2
- TRIML2 | c.*32del | 3'UTR (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel*, varscan2
